Somatic mutation profile of tumor specimen MMRF_2691_1_BM_CD138pos (aliquot MMRF_2691_1_BM_CD138pos_T1_KHS5U_L14416) from MMRF case MMRF_2691, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2691_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76c29bae-ccf8-4cce-97ec-cfd8afb9d4c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2691_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2691_1_PB_WBC_C2_KHS5U_L14417; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f51a7fc8-8572-41ba-9db2-0af22a36ce63

The open-access MAF lists 110 somatic variants for this specimen: 39 protein-altering or splice-affecting, 17 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 34, Silent 17, Intron 13, Nonsense Mutation 4, 5'UTR 3, 5'Flank 2, Splice Site 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPG5 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 74/232 reads (32%) | catalogued as rs961245497, CM163405, COSV56345253, COSV56352723; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59371453; called by muse, mutect2, varscan2
- ASTN2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57749553, COSV57783585; called by muse, varscan2
- CD19 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs768672649; called by muse, mutect2, varscan2
- DRD5 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58578518; called by muse, mutect2, varscan2
- EPHX4 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 52/142 reads (37%) | catalogued as rs1180811136, COSV100952731; called by muse, mutect2, varscan2
- H1-4 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV56799624, COSV56804339; called by muse, mutect2, varscan2
- HSPG2 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs758559575, COSV101021049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCH | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as rs765751827, COSV60052905; called by muse, mutect2, varscan2
- PCDHA6 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 71/547 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV100972421; called by muse, mutect2, varscan2
- RFWD3 | c.506C>G p.T169R | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs760743044; called by muse, mutect2, varscan2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX24 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754151591, COSV54450774; called by muse, mutect2, varscan2
- ZC3H11B | c.2368A>T p.I790F | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1202322911; called by muse, mutect2, varscan2
- CDH9 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2
- CILK1 | c.1838C>T p.P613L (on ENST00000350082 / NM_001375397.1; = p.P606L on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- CNGB3 | c.1573T>C p.F525L | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DSCAM | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- ERBIN | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRG2 | c.144T>G p.D48E | Missense Mutation (SNP) | VAF 126/281 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GUF1 | c.1282A>T p.T428S | Missense Mutation (SNP) | VAF 63/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHJ4 | c.4T>G p.F2V | Missense Mutation (SNP) | VAF 60/102 reads (59%) | PolyPhen benign (0); called by muse, varscan2
- KLF12 | c.146C>G p.P49R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KRT76 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MTMR14 | c.834T>A p.D278E | Missense Mutation (SNP) | VAF 217/411 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- NRTN | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR7A17 | c.339A>C p.L113F | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PEAK1 | c.4065C>G p.N1355K | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2
- SEC14L4 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SF3B1 | c.2600T>G p.M867R | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SF3B3 | c.1438A>G p.N480D | Missense Mutation (SNP) | VAF 11/387 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.174); called by muse, mutect2
- SOX6 | c.1966+2T>C p.X656_splice (on ENST00000528429 / NM_001145819.2; = p.X629_splice on NM_017508.3) | Splice Site (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- SYNJ1 | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM21 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- TSC22D1 | c.2426T>C p.V809A | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- WBP4 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZNF226 | c.2172G>C p.E724D | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACR | c.828G>A p.T276= | Silent (SNP) | VAF 22/204 reads (11%) | catalogued as rs1029429705; called by muse, mutect2, varscan2
- BTN3A1 | c.148C>T p.L50= | Silent (SNP) | VAF 12/296 reads (4%) | catalogued as rs1455123011; called by muse, mutect2
- DNAH7 | c.1302T>A p.I434= | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- FREM1 | c.3663T>C p.V1221= | Silent (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.108C>T p.T36= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs371944329; called by muse, mutect2
- IL17RD | c.2205G>A p.A735= | Silent (SNP) | VAF 75/372 reads (20%) | catalogued as rs924495358; called by muse, mutect2, varscan2
- IRX1 | c.483C>T p.I161= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- MPPED1 | c.213G>A p.P71= | Silent (SNP) | VAF 70/232 reads (30%) | catalogued as rs760492730, COSV61986891; called by muse, mutect2, varscan2
- NPFFR1 | c.696C>T p.I232= | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as rs898341268, COSV53331713; called by muse, mutect2, varscan2
- PARP3 | c.318G>A p.E106= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- RPE | c.501C>T p.F167= (on ENST00000359429 / NM_001318926.1; = p.F117= on NM_006916.2) | Silent (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- RSC1A1 | c.843T>C p.T281= | Silent (SNP) | VAF 83/222 reads (37%) | catalogued as rs1404588372; called by muse, mutect2, varscan2
- SMC4 | c.1077A>G p.S359= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- SUPT5H | c.564G>A p.E188= | Silent (SNP) | VAF 102/213 reads (48%) | called by muse, mutect2, varscan2
- TGM2 | c.984C>T p.S328= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as rs368023176; called by muse, mutect2
- TMEM37 | c.336C>G p.S112= | Silent (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- ZNF462 | c.4207C>T p.L1403= | Silent (SNP) | VAF 64/359 reads (18%) | called by muse, mutect2, varscan2
- AFAP1 | c.-3+49C>T | Intron (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- C1orf115 | c.*2227G>A | 3'UTR (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- CAND1 | c.*1585A>T | 3'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- CDS2 | c.*842G>A | 3'UTR (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- CILK1 | c.*3437C>T | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, varscan2
- CILK1 | c.*3436C>T | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, varscan2
- CILK1 | c.*3372C>T | 3'UTR (SNP) | VAF 12/80 reads (15%) | called by muse, varscan2
- CILK1 | c.*3305C>T | 3'UTR (SNP) | VAF 16/118 reads (14%) | catalogued as COSV100607669; called by muse, varscan2
- CILK1 | c.*2271C>T | 3'UTR (SNP) | VAF 14/92 reads (15%) | called by muse, varscan2
- CILK1 | c.*2210C>T | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, varscan2
- CILK1 | c.*1963C>T | 3'UTR (SNP) | VAF 33/143 reads (23%) | catalogued as rs1054460620; called by muse, varscan2
- CILK1 | c.*1884C>T | 3'UTR (SNP) | VAF 26/132 reads (20%) | called by muse, varscan2
- CILK1 | c.*1830C>T | 3'UTR (SNP) | VAF 12/97 reads (12%) | called by muse, varscan2
- CILK1 | c.*768G>A | 3'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, varscan2
- CILK1 | c.*684G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, varscan2
- CILK1 | c.*514G>A | 3'UTR (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- CILK1 | c.*142C>T | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CLEC5A | c.*2712A>G | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- COLGALT2 | c.*551_*552del | 3'UTR (DEL) | VAF 5/57 reads (9%) | called by pindel, varscan2*
- CYHR1 | c.247-116C>T | Intron (SNP) | VAF 76/176 reads (43%) | called by muse, mutect2, varscan2
- DDX1 | chr2:15591710 G>A | 5'Flank (SNP) | VAF 42/173 reads (24%) | called by muse, varscan2
- FAT1 | c.*498G>A | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- HEATR3 | c.*930C>T | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2
- HEXD | c.982+82C>G | Intron (SNP) | VAF 42/147 reads (29%) | catalogued as rs900585767; called by muse, mutect2, varscan2
- HSD17B12 | c.283+1251A>G | Intron (SNP) | VAF 48/96 reads (50%) | catalogued as rs1202691628; called by muse, mutect2, varscan2
- IGHM | chr14:105859490 C>A | 5'Flank (SNP) | VAF 7/12 reads (58%) | called by muse, varscan2
- IL21R | c.*1638T>A | 3'UTR (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
- KDM8 | c.*342del | 3'UTR (DEL) | VAF 20/139 reads (14%) | called by mutect2, pindel, varscan2
- LTB | c.209-60A>T | Intron (SNP) | VAF 23/94 reads (24%) | catalogued as COSV65815004; called by muse, mutect2, varscan2
- LTB | c.163-10A>G | Intron (SNP) | VAF 76/432 reads (18%) | called by muse, mutect2, varscan2
- LVRN | c.2038-112C>T | Intron (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2
- MIA2 | c.64-485C>T | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- MIR380 | n.56C>T | RNA (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- NCAPH2 | c.*1099_*1114del | 3'UTR (DEL) | VAF 78/502 reads (16%) | called by mutect2, pindel, varscan2
- NET1 | c.*1004del | 3'UTR (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- NNMT | c.*476G>A | 3'UTR (SNP) | VAF 73/135 reads (54%) | called by muse, mutect2, varscan2
- NPTXR | c.*378G>A | 3'UTR (SNP) | VAF 25/104 reads (24%) | catalogued as rs976066104; called by muse, mutect2, varscan2
- NR4A3 | c.1254+104A>C | Intron (SNP) | VAF 92/484 reads (19%) | called by muse, mutect2, varscan2
- NTRK3 | c.*6159C>A | 3'UTR (SNP) | VAF 96/208 reads (46%) | called by muse, mutect2, varscan2
- PCDH17 | c.*1741C>A | 3'UTR (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- PDE3B | c.1279-76C>T | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- PDZD4 | c.*82T>C | 3'UTR (SNP) | VAF 12/51 reads (24%) | catalogued as rs1441605141; called by muse, mutect2, varscan2
- PDZRN3 | c.-91C>T | 5'UTR (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*5195C>A | 3'UTR (SNP) | VAF 60/206 reads (29%) | called by muse, mutect2, varscan2
- RPA1 | c.1552-93A>G | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs55673091; called by muse, varscan2
- SACM1L | c.333+26T>C | Intron (SNP) | VAF 54/272 reads (20%) | catalogued as rs772469918; called by muse, mutect2
- SENP1 | c.*219A>G | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- SMARCB1 | chr22:23835875 C>T | 3'Flank (SNP) | VAF 86/140 reads (61%) | catalogued as rs988021877; called by muse, mutect2, varscan2
- STYX | c.-263T>G | 5'UTR (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- STYX | c.-262A>G | 5'UTR (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- UCP1 | c.*187G>A | 3'UTR (SNP) | VAF 26/126 reads (21%) | called by mutect2, varscan2
- USH2A | c.4627+889dup | Intron (INS) | VAF 24/60 reads (40%) | catalogued as rs773136439; called by mutect2, varscan2
- WASF1 | c.*257G>T | 3'UTR (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- ZNF594 | c.*1429A>G | 3'UTR (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
